TCGA case TCGA-VT-AB3D — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Vanderbilt. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4d67b910-6681-45a4-9dac-6a12d67287a8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Undifferentiated sarcoma: ICD-O-3 morphology code: 8805/3; ICD-10 code: C49.10; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Classification of tumor: primary; Age at diagnosis: 71.5 years (26,100 days); Year of diagnosis: 2013; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis present: No; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 3.4; Tumor length measurement: 5.6; Tumor width measurement: 4.2.
   Pathology details: Measurement type: Pathologic; Tumor burden: 4.2.
   Pathology details: Measurement type: Radiologic; Tumor burden: 5.6.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 2.5; Tumor length measurement: 4.2; Tumor width measurement: 4.

Follow-up (3 entries)
- Days to follow up: -7 days; Disease response: Tumor Free.
- Day 0 (initial diagnosis): Discontiguous lesion count: 0.
- Days to follow up: 379 days (1.0 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 13.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VT-AB3D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 90 mg.
  Slide TCGA-VT-AB3D-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 96; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-VT-AB3D-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VT-AB3D-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Undifferentiated Pleomorphic Sarcoma (UPS); Margin status: Negative; Tumor total necrosis: 0% (no necrosis or no mention of necrosis); Disease multifocal indicator: No; Discontinuous lesions count: 0; Locoregional recurrence indicator: No; Metastatic disease confirmed: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Upper Extremity - Upper arm/elbow.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic width: 4.0.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Stable Disease; New tumor event diagnosis indicator: No.
- Radiation treatment: Days from index date to radiation therapy started: 42; Days from index date to radiation therapy ended: 90; Radiation therapy type: External; Radiation total dose: 60; Radiation adjuvant units: Gy; Radiation adjuvant fractions total: 30; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No; Treatment best response: Complete Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 379 days; disease-specific survival: no event (censored), 379 days; disease-free interval: no event (censored), 379 days; progression-free interval: no event (censored), 379 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VT-AB3D-01A-12D-A416-01): tumor purity 0.29, ploidy 1.86, whole-genome doublings 0.
